Somatic mutation profile of tumor specimen TCGA-C5-A1MI-01A (aliquot TCGA-C5-A1MI-01A-11D-A14W-08) from TCGA case TCGA-C5-A1MI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 50.2 years (18,336 days).
Specimen TCGA-C5-A1MI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba8160c7-44ad-488b-8faa-00497429b9ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A1MI-10A (Blood Derived Normal), aliquot TCGA-C5-A1MI-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3fd5afe7-9e69-4ea8-ab01-80e41783d795

The open-access MAF lists 64 somatic variants for this specimen: 40 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 22, Nonsense Mutation 2, RNA 1, Nonstop Mutation 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 30/137 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.2917C>T p.R973W | Missense Mutation (SNP) | VAF 5/15 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1218643327, COSV60787034; called by muse, mutect2, varscan2
- ABCA5 | c.3157A>G p.T1053A | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT tolerated (0.66); PolyPhen benign (0.372); catalogued as COSV67018199; called by muse, mutect2, varscan2
- ABCB6 | c.2267C>T p.A756V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1251196290, COSV54695517; called by muse, mutect2
- ADAMTSL3 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV54459886; called by muse, mutect2, varscan2
- ANKFY1 | c.2908G>A p.E970K (on ENST00000341657 / NM_001330063.2; = p.E971K on NM_016376.5) | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.721); catalogued as COSV58920350; called by muse, mutect2, varscan2
- ARID1A | c.4087C>T p.Q1363* | Nonsense Mutation (SNP) | VAF 39/120 reads (33%) | catalogued as COSV61381868; called by muse, mutect2, varscan2
- ATP2C2 | c.2830G>A p.E944K | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.011); catalogued as rs1199757472, COSV52299344; called by muse, mutect2, varscan2
- BAHCC1 | c.2564C>A p.S855Y | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57030932; called by muse, mutect2, varscan2
- BGN | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs782525620, COSV59036425; called by muse, mutect2, varscan2
- BRD1 | c.2020G>A p.G674S | Missense Mutation (SNP) | VAF 41/59 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1299311239, COSV53460054; called by muse, mutect2, varscan2
- CMSS1 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV101375532, COSV70440029; called by muse, mutect2, varscan2
- DISP1 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.115); catalogued as COSV52662723; called by muse, mutect2, varscan2
- FAM228A | c.327C>A p.F109L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.029); catalogued as COSV99039432; called by muse, mutect2, varscan2
- FERMT3 | c.2003G>C p.*668Sext*44 (on ENST00000279227 / NM_178443.3; = p.*664Sext*44 on NM_031471.6 and 3 other RefSeq transcripts) | Nonstop Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV54174999; called by muse, mutect2, varscan2
- FLG | c.2669G>A p.R890K | Missense Mutation (SNP) | VAF 356/651 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV64235539; called by muse, varscan2
- GALNT5 | c.1692G>C p.E564D | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as COSV52038988, COSV52039736; called by muse, mutect2, varscan2
- GPT2 | c.1259C>G p.T420R | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV100412923, COSV60839604; called by muse, mutect2, varscan2
- HNRNPL | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.018); catalogued as COSV55494415; called by muse, mutect2
- IGSF11 | c.268G>A p.G90S (on ENST00000393775 / NM_001015887.3; = p.G89S on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs759581949, COSV61169150; called by muse, mutect2, varscan2
- IGSF9B | c.2500G>A p.V834M | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs771150072, COSV58068494; called by muse, mutect2, varscan2
- KALRN | c.4859A>G p.D1620G | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1417424509, COSV53774639; called by muse, varscan2
- KIF7 | c.3989G>C p.R1330P | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV51544992; called by muse, mutect2, varscan2
- KLHL1 | c.1459A>T p.I487F | Missense Mutation (SNP) | VAF 66/125 reads (53%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.511); catalogued as COSV100917131, COSV64777801; called by muse, mutect2, varscan2
- MAP1B | c.3824G>A p.R1275H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs372421201; called by muse, mutect2, varscan2
- MMEL1 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs374379604; called by muse, mutect2, varscan2
- NEK6 | c.239A>T p.E80V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV57220034; called by muse, mutect2, varscan2
- NT5DC2 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV61053221; called by muse, mutect2, varscan2
- OR2L3 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63455879; called by muse, mutect2, varscan2
- PCLO | c.2653G>A p.A885T | Missense Mutation (SNP) | VAF 68/227 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201657775, COSV100437922; called by muse, mutect2, varscan2
- RAI1 | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV55396427; called by muse, mutect2, varscan2
- RAPGEF2 | c.2948A>G p.N983S | Missense Mutation (SNP) | VAF 63/90 reads (70%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs781005071, COSV52431794; called by muse, mutect2, varscan2
- SCAPER | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 6/142 reads (4%) | catalogued as rs1342697252, COSV57733626; called by muse, mutect2
- SIGLEC11 | c.1003C>G p.R335G | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs747255098, COSV70222089; called by mutect2, varscan2
- TSKS | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs775796223, COSV55877774; called by mutect2, varscan2
- TUBGCP2 | c.2487C>G p.F829L | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99428351; called by muse, mutect2
- UBR4 | c.5830C>T p.R1944C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV64395435; called by muse, mutect2, varscan2
- ZNF75D | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV66133214; called by muse, mutect2, varscan2
- GLT8D2 | c.189del p.A64Pfs*21 | Frame Shift Del (DEL) | VAF 29/132 reads (22%) | called by mutect2, pindel, varscan2
- KIR3DL2 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 106/364 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, varscan2
- ADGRE5 | c.1758C>G p.L586= (on ENST00000242786 / NM_078481.4; = p.L493= on NM_001784.5) | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV54392766; called by muse, mutect2, varscan2
- ANKRD53 | c.864G>A p.Q288= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs1408077001, COSV55538530; called by muse, mutect2, varscan2
- ANKRD6 | c.282C>T p.L94= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV60234496; called by muse, mutect2, varscan2
- ARID3A | c.1086G>A p.S362= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs374271087; called by muse, mutect2, varscan2
- CBLN1 | c.507C>T p.L169= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as COSV54654681; called by muse, mutect2, varscan2
- DTD1 | c.231C>A p.V77= | Silent (SNP) | VAF 55/105 reads (52%) | catalogued as COSV66281237; called by muse, mutect2, varscan2
- FHOD1 | c.924G>A p.A308= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as COSV50765447; called by muse, mutect2, varscan2
- GALNS | c.1161C>T p.G387= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs376919708; called by muse, mutect2, varscan2
- GNRH2 | c.30C>G p.L10= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV55662120; called by muse, mutect2, varscan2
- HCN4 | c.2334C>T p.I778= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV56085889; called by muse, mutect2, varscan2
- IPCEF1 | c.115C>T p.L39= | Silent (SNP) | VAF 65/110 reads (59%) | catalogued as COSV54548211; called by muse, mutect2, varscan2
- NIPSNAP3B | c.378G>A p.T126= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs146813577, COSV101044429, COSV66106804; called by muse, mutect2, varscan2
- POM121 | c.3336G>A p.G1112= (on ENST00000434423; = p.G847= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV57521283; called by muse, mutect2, varscan2
- PPFIA3 | c.3372C>T p.F1124= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV53257688; called by muse, mutect2, varscan2
- RAF1 | c.72C>G p.G24= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV52581846; called by muse, mutect2, varscan2
- RHOBTB3 | c.198C>G p.V66= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV66102717; called by muse, mutect2, varscan2
- SFXN2 | c.765C>T p.F255= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV64012954; called by muse, mutect2, varscan2
- SMYD5 | c.267G>A p.G89= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs1240202075, COSV50265424; called by muse, mutect2, varscan2
- TLL1 | c.1677C>T p.D559= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs142933283; called by muse, mutect2, varscan2
- TRRAP | c.1884G>A p.E628= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs1554408648, COSV100723003; called by muse, mutect2, varscan2
- TSC2 | c.1680G>T p.V560= | Silent (SNP) | VAF 57/183 reads (31%) | catalogued as COSV54760264, COSV54774033; called by muse, mutect2, varscan2
- ZFAND4 | c.867C>G p.P289= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as COSV100762994, COSV60860570; called by muse, mutect2, varscan2
- AC244258.1 | n.571C>T | RNA (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- GARRE1 | c.-2G>A | 5'UTR (SNP) | VAF 24/143 reads (17%) | catalogued as rs535765849, COSV100209119; called by muse, mutect2, varscan2
